TCGA case TCGA-CG-4466 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2f1b96b2-7031-4f7d-9490-14728d320f3e

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 81 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, intestinal type: ICD-O-3 morphology code: 8144/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 81.4 years (29,739 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 577 days (1.6 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 13.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 577 days (1.6 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CG-4466-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.7; Shortest dimension: 0.3.
  Slide TCGA-CG-4466-01A-01-BS1: Section location: Bottom; Percent tumor cells: 82; Percent tumor nuclei: 75; Percent normal cells: 3; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-CG-4466-01A-01-TS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 75; Percent normal cells: 3; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-CG-4466-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CG-4466-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Anatomic organ subdivision: Cardia/Proximal; Lymph nodes examined: Yes; Cancer procurement city: Hamburg.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 577 days; disease-specific survival: no event (censored), 577 days; disease-free interval: no event (censored), 577 days; progression-free interval: no event (censored), 577 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CG-4466-01A-01D-1155-01): tumor purity 0.79, ploidy 3.74, whole-genome doublings 2.
